Somatic mutation profile of tumor specimen 0DUVTQ from CCDI case PBCLSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.2 years (791 days).
Specimen 0DUVTQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6240946a-24ee-4e50-95c2-95255872702a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d106c8b0-67ea-441e-8eb6-7ca6f2d566b9

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD7 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 303/662 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1174442449, COSV54554414, COSV54556600; called by muse, mutect2, varscan2
- APC | c.1042del p.R348Dfs*106 | Frame Shift Del (DEL) | VAF 141/218 reads (65%) | catalogued as CM013690, COSV57335557; called by mutect2, varscan2
- EVX2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV57962625; called by muse, mutect2, varscan2
- GP5 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778829280, COSV59878752; called by muse, mutect2, varscan2
- LTN1 | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 347/876 reads (40%) | catalogued as COSV63734530; called by muse, mutect2, varscan2
- MYO7B | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 122/462 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs202039269, COSV67346280; called by muse, mutect2, varscan2
- ZFHX2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs61740283; called by muse, mutect2, varscan2
- CFTR | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 287/766 reads (37%) | called by muse, mutect2, varscan2
- MROH9 | c.710A>T p.D237V | Missense Mutation (SNP) | VAF 83/1209 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2
- MUC2 | c.2398T>A p.C800S | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KLHDC7B | c.1365C>T p.T455= (on ENST00000395676; = p.T1096= on NM_138433.5) | Silent (SNP) | VAF 93/238 reads (39%) | catalogued as rs760260427, COSV101192898; called by muse, mutect2, varscan2
- MAP1S | c.1047G>A p.A349= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs760557907; called by muse, mutect2, varscan2
- TUBA3E | c.981C>T p.D327= | Silent (SNP) | VAF 147/497 reads (30%) | catalogued as rs769094132, COSV56059778; called by muse, mutect2, varscan2
